Somatic mutation profile of tumor specimen TCGA-DU-6400-01A (aliquot TCGA-DU-6400-01A-12D-1705-08) from TCGA case TCGA-DU-6400, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 66.0 years (24,122 days).
Specimen TCGA-DU-6400-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60392136-f7cb-48dc-b05b-48cac8db6df0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6400-10A (Blood Derived Normal), aliquot TCGA-DU-6400-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a3aa527-583d-491e-bc40-4ea1d9cb4a30

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Frame Shift Del 3, Nonsense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50579323, COSV50627795; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/82 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1057523819, COSV53030190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as rs1036743889, COSV59607187; called by muse, mutect2, varscan2
- ACTL9 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as rs1427782355, COSV61005980; called by muse, mutect2, varscan2
- ADGRF5 | c.2167G>A p.A723T | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); catalogued as COSV51934545; called by muse, mutect2, varscan2
- APOB | c.9026T>A p.L3009Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.999); catalogued as COSV51937632; called by muse, mutect2, varscan2
- BRINP1 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV56301399; called by muse, mutect2, varscan2
- CBLB | c.455A>T p.H152L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51427777; called by muse, mutect2, varscan2
- CCDC113 | c.546+1G>A p.X182_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV54686233; called by muse, mutect2, varscan2
- CIC | c.1183del p.Y395Mfs*40 | Frame Shift Del (DEL) | VAF 27/61 reads (44%) | catalogued as COSV50657036; called by mutect2, pindel, varscan2
- DCAF8L1 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV71595143, COSV71595321; called by muse, mutect2, varscan2
- DLX4 | c.707C>T p.S236L (on ENST00000240306 / NM_138281.3; = p.S164L on NM_001934.3) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs202154782; called by muse, mutect2, varscan2
- DNAH10 | c.11482G>A p.A3828T (on ENST00000409039; = p.A3767T on NM_207437.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs183103487; called by muse, mutect2, varscan2
- DPY19L2 | c.840C>G p.C280W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV60543711; called by muse, mutect2, varscan2
- E4F1 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV57039300; called by muse, mutect2, varscan2
- EDDM3B | c.137G>C p.R46T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58747072, COSV58747247; called by muse, mutect2, varscan2
- FBXO42 | c.1303G>T p.G435C | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as COSV100981649; called by muse, varscan2
- GALNTL5 | c.1055T>A p.I352K | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV67180269; called by muse, mutect2, varscan2
- ITIH6 | c.3466A>G p.T1156A | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV54489697; called by muse, mutect2, varscan2
- KIAA1217 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775612291, COSV64606789; called by muse, mutect2, varscan2
- KIFC2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as COSV56761207; called by muse, mutect2, varscan2
- LMOD2 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71755659; called by muse, mutect2
- LRRC8B | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 58/67 reads (87%) | catalogued as rs773870761, COSV58375002; called by muse, mutect2, varscan2
- METTL25 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); catalogued as rs1468212072, COSV50259309; called by muse, mutect2, varscan2
- NMD3 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs754913920, COSV63618650; called by muse, mutect2, varscan2
- PGAM2 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV51978389; called by muse, mutect2, varscan2
- PPIG | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.779); catalogued as COSV53643421; called by muse, mutect2, varscan2
- RTL9 | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 106/258 reads (41%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.571); catalogued as rs867836656, COSV71825671; called by muse, mutect2, varscan2
- SLC6A3 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54364738; called by muse, mutect2, varscan2
- SPDL1 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54668320; called by muse, mutect2
- TTC14 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761569697, COSV56011499; called by muse, mutect2, varscan2
- ULK4 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV57210420; called by muse, mutect2
- WAS | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV64997216; called by muse, mutect2, varscan2
- ZBED1 | c.1496A>T p.E499V | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV58134350; called by muse, mutect2, varscan2
- ZC3H12B | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59048371; called by muse, mutect2, varscan2
- ZNF292 | c.3886del p.H1296Ifs*15 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as COSV60535176; called by mutect2, varscan2
- ZW10 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs1437048551, COSV52316858; called by muse, mutect2, varscan2
- TBC1D8B | c.123del p.L42Sfs*19 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.672G>A p.R224= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as COSV54957384; called by muse, mutect2
- ALDH3B2 | c.159C>T p.C53= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1365585332, COSV62428453; called by muse, mutect2
- DENND1A | c.879G>A p.L293= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV65326369; called by muse, mutect2
- DSPP | c.819T>C p.S273= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV56810919; called by muse, mutect2, varscan2
- MROH2B | c.3996C>T p.S1332= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs542700965, COSV68184792; called by muse, mutect2, varscan2
- N4BP3 | c.405G>A p.A135= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs377627701; called by muse, mutect2, varscan2
- NUDT10 | c.63G>A p.A21= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV62854015; called by muse, mutect2, varscan2
- PCDH11X | c.207C>T p.T69= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as rs756498510, COSV53445853, COSV53493669; called by muse, mutect2, varscan2
- PIEZO2 | c.7677T>C p.N2559= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV53289997; called by muse, mutect2
- PLIN4 | c.2793C>T p.T931= (on ENST00000301286; = p.T946= on NM_001367868.2) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs551750122, COSV56692131; called by muse, mutect2, varscan2
- SLC11A1 | c.1344G>A p.T448= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs375573580; called by muse, mutect2, varscan2
- SLC6A2 | c.1227C>T p.F409= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs149035289; called by muse, mutect2
- SVIL | c.2040C>T p.V680= (on ENST00000355867 / NM_021738.3; = p.V286= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs748555767, COSV63443861; called by muse, mutect2, varscan2
- TACC1 | c.1392-1302A>G | Intron (SNP) | VAF 41/134 reads (31%) | catalogued as COSV99392961; called by muse, mutect2, varscan2
